Surgical pathology report (de-identified scan), TCGA case TCGA-SH-A7BH, project TCGA-MESO (Mesothelioma), tissue source site Papworth Hospital, specimen TCGA-SH-A7BH-01A (Primary Tumor).

Sex: F

Date Collected:

Date Received:

Date Printed:

Copy To:

SPECIMEN DETAILS

Pleural biopsies, right

CLINICAL INFORMATION

SOBOE

Right pleural effusion

Known sarcomatoid mesothelioma Per TSS, known sarcomatoid on (L) side.

Previous L LAT - pleurodesed Per TSS, pleurodesis took place 10 minutes after procurement.

Ex-smoker

Asbestos exposure known

MACROSCOPIC DESCRIPTION

Two pieces of red and cream coloured tissue measuring 0.8 x 0.8 x 0.3 cm and 1 x 0.5 x 0.3 cm in maximum dimension respectively.

2 in 1 AP

MICROSCOPIC REPORT

The sections reveal irregular pieces of pleural tissue diffusely infiltrated a biphasic tumour showing areas of epithelioid tumour cells with visible nucleoli and a moderate amount of cytoplasm, which merge with areas of tumour displaying a more sarcomatoid morphology with oval to plump spindle shaped cells set in fibrous stroma.

Per TSS, TCGA tumor is 65% epithelioid and 35% sarcomatoid, BCR

Immunohistochemistry - The tumour, mainly in the epithelioid areas, is variably positive for MNF116, AE1AE3, CD34, Bcl-2, CD99 (weak) and EMA (weak, focally membranous), but shows only one small focus where a few cells stain for calretinin. There is no significant staining for CK5/6, mesothelin, CD31, HMB45 and TTF-1. WT-1 shows variable cytoplasmic staining, but no significant nuclear positivity.

Despite the lack of specific staining for mesothelial markers, the morphological appearances favour biphasic mesothelioma.

Clinical-radiological-pathological correlation is advised.

Reporting Pathologist:

Authorising Pathologist:

Source: NCI Genomic Data Commons file 5715efdc-8a9a-4023-8a57-686572ab0fb4 (TCGA-SH-A7BH.87BA5B63-D23C-4A1F-AFEB-0FD9DB9EE7C4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).